Surgical pathology report (de-identified scan), TCGA case TCGA-83-5908, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site CHI-Penrose Colorado, specimen TCGA-83-5908-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

SPECIMEN

- A. LUNG - 1. Needle biopsy left upper lung lobe mass - [REDACTED]
- B. LUNG - 2. Left upper lung lobe - FS for Margen's
- C. LYMPH NODE(S) - 3. Level 10 lymph node
- D. LYMPH NODE(S) - 4. Level 7 lymph node
- E. LYMPH NODE(S) - 5. Level 8 nodes
- F. LYMPH NODE(S) - 6. Level 9 nodes

CLINICAL INFORMATION

Left lung mass.

[REDACTED]

GROSS DESCRIPTION

The specimens are received in six containers, each labeled with the patient's name [REDACTED]

Part A is received fresh for frozen section diagnosis labeled "needle biopsy left upper lung lobe" and consists of seven cylindrical portions of tan-white tissue ranging from 0.1 x 0.1 cm up to 0.5 x 0.1 cm. The specimen is submitted in toto for frozen section diagnosis as (FSA1). The frozen section residue is submitted as (A1).

Frozen section diagnosis:

FSA1 – Needle biopsy left upper lobe – "positive for non-small-cell carcinoma."

[REDACTED]

Part B is received fresh for frozen section diagnosis labeled "left upper lobe" and consists of a 125 gm, 12 x 8 x 4 cm lobe of lung including a 0.5 cm length of exposed bronchus. The mildly anthracotic pleura has a 1 cm retracted area over a palpable mass near the hilum. The bronchial margin is taken en face and submitted for frozen section diagnosis as (FSB1). Sections show a well-defined 2.5 x 2.5 x 2 cm firm tan-white subpleural mass, which corresponds to the pleural retraction and is located approximately 1 cm from the bronchial margin. The mass grossly communicates with the bronchus. The remainder of the specimen consists of spongy light-grey parenchyma without additional nodules or areas of consolidation.

[REDACTED]

[page 2 of 4]
A 0.5 cm peribronchial lymph node is dissected from the specimen. The frozen section residue and representative sections are submitted as (B1)-(B7).

SLIDE KEY

B1 – Bronchial margin en face for frozen section
B2 – Vascular margin en face
B3 – Tumor with inked pleura
B5-B5 – Tumor
B6 – Uninvolved parenchyma
B7 – One lymph node bisected

Frozen section diagnosis:

FSB1 – Left upper lobe bronchial margin – "Negative for carcinoma."

Examined by [REDACTED]

Part C is received fresh labeled "level 10 lymph nodes" are four anthracotic tan tissue fragments ranging from 0.3 cm-0.8 cm. The specimen is submitted in toto as (C1).

Part D is received fresh labeled "level 7 lymph nodes" and consists of two 0.8 cm and 1.9 cm portions of tan tissue. The specimen contains two 1.7 cm and 0.6 cm anthracotic lymph nodes. Poles were bisected and the specimen is submitted in its entirety with one lymph node per cassette as (D1) and (D2).

Part E is received fresh labeled "level 8 lymph nodes" and consists of a 1.5 cm portion of adipose tissue, which contains a 1 cm anthracotic lymph node. The lymph node is bisected and submitted in its entirety as (E1).

Part F is received fresh labeled "level 9 lymph nodes" and consists of a 1.4 cm portion of adipose tissue, which contains a 0.7 cm anthracotic lymph node. The lymph node is bisected and submitted in its entirety as (F1). [REDACTED]

MICROSCOPIC DESCRIPTION

SURGICAL PATHOLOGY CANCER CASE SUMMARY, LUNG

LUNG: Resection.

SPECIMEN TYPE: Left upper lobe lobectomy.

TUMOR SITE: Left upper lobe.

TUMOR SIZE: 2.5 x 2.5 x 2 cm.

HISTOLOGIC TYPE: Adenocarcinoma.

HISTOLOGIC GRADE: The tumor shows solid nests of cells as well as areas where the tumor lines glandular spaces. The majority of the tumor is solid. There is a focally marked pleomorphism in the tumor cells with large high irregular and lobated nuclei. Mitotic figures are fairly abundant. The tumor is situated within desmoplastic stroma, which is moderately inflamed.

EXTENT OF INVASION: The tumor comes close to the visceral epithelial cell surface and, therefore, and elastin stain was performed with an appropriate control. The tumor comes close to, but does not invade through the elastin fibers.

T1, tumor 3 cm or less in greatest dimension, surrounded by lung and visceral pleura.

[REDACTED]

[page 3 of 4]
[REDACTED]

MARGINS: Margins uninvolved by tumor.
Distance of tumor from closest margin: 1 cm.
ARTERIAL, VENOUS/LYMPHATIC VESSEL INVASION: Absent.
REGIONAL LYMPH NODES: N0, no regional lymph node metastasis.
A total of 9 lymph nodes are examined, none of which are positive (0/9).
LOBECTOMY LYMPH NODES:
Number examined: 1.
Number positive: 0.
LEVEL 10 LYMPH NODES:
Number examined: 4.
Number positive: 0.
LEVEL 7 LYMPH NODES:
Number examined: 2.
Number positive: 0.
LEVEL 8 LYMPH NODE:
Number examined: 1
Number positive: 0.
LEVEL 9 LYMPH NODE:
Number examined: 1
Number positive: 0.
DISTANT METASTASIS: MX, cannot be assessed.
PATHOLOGIC TNM STAGE: IA (T1 N0 MX).
[REDACTED]

FINAL DIAGNOSIS

LUNG, LEFT UPPER LOBE, BIOPSY

- Moderately differentiated invasive adenocarcinoma.

LUNG, LEFT UPPER LOBE, LOBECTOMY

- Invasive, moderately differentiated adenocarcinoma.
- Tumor measures 2.5 cm in greatest dimension.
- No evidence of vascular invasion.
- 1 lymph node negative for metastatic carcinoma (0/1).

LEVEL 10 LYMPH NODES, DISECTION

- 4 lymph nodes negative for metastatic carcinoma (0/4).

LEVEL 7 LYMPH NODES, DISECTION

- 2 lymph nodes negative for metastatic carcinoma (0/2).

LEVEL 8 LYMPH NODE, BIOPSY

- 1 lymph node negative for metastatic carcinoma (0/1).

LEVEL 9 LYMPH NODES, BIOPSY

- 1 lymph node negative for metastatic carcinoma (0/1).

CPT CODE(S): 88309X1, 88307X2, 88305X3, 88331X2, 88313

[REDACTED]

Source: NCI Genomic Data Commons file 3a106c57-c506-4a63-820a-72e71c8fc9b0 (TCGA-83-5908.BF81E5A3-26DB-4476-B553-38D4F6897309.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).